CCDI case PBBPVR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Testis.
https://portal.gdc.cancer.gov/cases/a0bc7ddc-3f4c-4ae3-ab05-3af356cf15f0

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 19.1 years (6,970 days).

Biospecimens (3 samples)
- Sample 0DF84N: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DF84O: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DF84Q: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
